Somatic mutation profile of tumor specimen TCGA-XP-A8T7-01A (aliquot TCGA-XP-A8T7-01A-11D-A36J-09) from TCGA case TCGA-XP-A8T7, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 64.0 years (23,375 days).
Specimen TCGA-XP-A8T7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c03caa12-ff16-4d5f-9402-628637998c03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XP-A8T7-10A (Blood Derived Normal), aliquot TCGA-XP-A8T7-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e96a3353-2677-42d8-9196-ec2969c25fc0

The open-access MAF lists 95 somatic variants for this specimen: 66 protein-altering or splice-affecting, 25 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 25, Frame Shift Del 5, Nonsense Mutation 3, Splice Site 2, Frame Shift Ins 2, Intron 1, 3'UTR 1, Splice Region 1, RNA 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.458-1G>A p.X153_splice | Splice Site (SNP) | VAF 40/67 reads (60%) | hotspot (GDC flag); catalogued as CS127044, COSV58686546, COSV58687455, COSV58704542; called by muse, mutect2, varscan2
- FBXW7 | c.1177C>T p.R393* (on ENST00000281708 / NM_001349798.2; = p.R313* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 31/38 reads (82%) | hotspot (GDC flag); catalogued as COSV55892695; called by muse, mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 36/136 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANK3 | c.9652C>A p.L3218I | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.006); catalogued as CM1512392; called by muse, mutect2, varscan2
- AP1M1 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.089); catalogued as rs1218074745, COSV52228789; called by muse, mutect2, varscan2
- BLM | c.3262G>T p.V1088F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs934966838; called by muse, mutect2, varscan2
- CD300A | c.668C>G p.A223G | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.116); catalogued as COSV60409410; called by muse, mutect2, varscan2
- CDH10 | c.2198T>A p.L733H | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100050052; called by muse, mutect2, varscan2
- CFAP58 | c.1864G>A p.D622N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV100866119; called by muse, mutect2, varscan2
- CILK1 | c.1448G>A p.R483Q (on ENST00000350082 / NM_001375397.1; = p.R476Q on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs55895113; called by muse, mutect2, varscan2
- CMYA5 | c.4868A>G p.E1623G | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1554034091, COSV101483732; called by muse, mutect2, varscan2
- COL4A3 | c.4238C>T p.S1413F | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.025); catalogued as rs373382431; called by muse, mutect2, varscan2
- COL5A2 | c.4076C>T p.P1359L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs745580343; called by muse, mutect2, varscan2
- ERICH3 | c.1550G>A p.G517E | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV58598618; called by muse, mutect2, varscan2
- FMN2 | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100143833, COSV60431694; called by muse, mutect2, varscan2
- GLUD1 | c.1100A>G p.Y367C | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as rs766896575; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSPA6 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59059917; called by muse, mutect2, varscan2
- KIAA1109 | c.2758G>T p.A920S | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV99063741; called by muse, mutect2, varscan2
- LAMA1 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.573); catalogued as rs377017068; called by muse, mutect2, varscan2
- LFNG | c.594C>A p.H198Q (on ENST00000222725 / NM_001040167.2; = p.H69Q on NM_002304.2) | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56070889; called by muse, mutect2, varscan2
- LRFN5 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs548468008, COSV53243796; called by muse, mutect2, varscan2
- MYCBP2 | c.6239T>A p.L2080H (on ENST00000357337; = p.L2118H on NM_015057.5) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.575); catalogued as rs1376418975; called by muse, mutect2, varscan2
- NCDN | c.1417G>A p.V473I | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs956053377, COSV61936878; called by muse, mutect2, varscan2
- NPAP1 | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as COSV61507005; called by muse, mutect2, varscan2
- PPP2R1A | c.443G>A p.C148Y | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV59045836; called by muse, mutect2, varscan2
- RASGEF1A | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs760968520; called by muse, mutect2, varscan2
- SCNN1B | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs763646515; called by muse, varscan2
- SEPTIN4 | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.006); catalogued as rs373119715; called by muse, mutect2, varscan2
- SEZ6L | c.1585C>A p.P529T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50692927; called by muse, mutect2, varscan2
- SORCS3 | c.1039G>A p.G347R | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as rs530482370; called by muse, mutect2, varscan2
- SYNE3 | c.2363G>A p.R788K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV62079517; called by muse, mutect2, varscan2
- TP53 | c.876del p.E294Sfs*51 | Frame Shift Del (DEL) | VAF 36/61 reads (59%) | catalogued as COSV52795860, COSV53037721, COSV53188887; called by mutect2, pindel, varscan2
- TRO | c.1694G>A p.R565H | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs201094980, COSV51499655; called by muse, mutect2, varscan2
- UGT1A7 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs371311391; called by muse, mutect2, varscan2
- UNC5B | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104407342; called by muse, mutect2, varscan2
- YAP1 | c.1414C>G p.P472A (on ENST00000282441 / NM_001130145.3; = p.P418A on NM_006106.5) | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56774518; called by muse, mutect2, varscan2
- ACACA | c.2980G>C p.E994Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- ALDH1A2 | c.775A>C p.I259L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ALPK3 | c.2174A>T p.E725V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ANKMY1 | c.1906C>T p.L636F | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATXN10 | c.627A>T p.K209N | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- C10orf99 | c.75G>C p.K25N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CDH10 | c.952G>C p.D318H | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- CYP4X1 | c.620G>A p.S207N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DNAH3 | c.10633G>C p.G3545R | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- GLYCTK | c.1474T>A p.F492I | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- KMT2D | c.8727_8730del p.S2910Rfs*32 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | called by mutect2, pindel, varscan2
- LAMP3 | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- MAGEA6 | c.862C>A p.H288N | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- MBOAT7 | c.1032_1034del p.S345del | In Frame Del (DEL) | VAF 19/70 reads (27%) | called by mutect2, pindel, varscan2
- MYO3B | c.1418_1421del p.S473Wfs*25 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- NOC4L | c.1003dup p.D335Gfs*18 | Frame Shift Ins (INS) | VAF 16/79 reads (20%) | called by mutect2, pindel, varscan2
- NOXRED1 | c.682+8C>A | Splice Region (SNP) | VAF 38/59 reads (64%) | called by muse, mutect2, varscan2
- NPAT | c.557-2A>T p.X186_splice | Splice Site (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2, varscan2
- NUCB1 | c.1378_1384del p.H460Dfs*17 | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | called by mutect2, pindel, varscan2
- OR5L2 | c.140C>A p.A47E | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- PCGF2 | c.642del p.Y215Tfs*24 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | called by mutect2, varscan2
- PIP4P2 | c.359A>T p.N120I | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RLF | c.5068C>T p.Q1690* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2
- SEC16A | c.6575G>C p.R2192P | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SPATA31E1 | c.2824A>G p.T942A | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- TAF6L | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TGDS | c.862dup p.W288Lfs*3 | Frame Shift Ins (INS) | VAF 29/97 reads (30%) | called by mutect2, pindel, varscan2
- UPK3A | c.531G>C p.E177D | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZNF445 | c.1437C>A p.H479Q | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); called by muse, mutect2
- ZNF804B | c.1841G>T p.R614I | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- APEX2 | c.1556G>A p.*519= | Silent (SNP) | VAF 21/38 reads (55%) | called by muse, mutect2, varscan2
- ARHGEF10 | c.3462C>T p.N1154= (on ENST00000398564; = p.N1129= on NM_014629.4) | Silent (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2
- CIT | c.6039C>T p.T2013= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- DGKG | c.1866G>A p.S622= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs547522584; called by muse, mutect2, varscan2
- GCNA | c.396C>T p.N132= | Silent (SNP) | VAF 23/80 reads (29%) | called by muse, mutect2, varscan2
- GPBP1 | c.51A>G p.P17= | Silent (SNP) | VAF 41/54 reads (76%) | called by muse, mutect2, varscan2
- HCRTR1 | c.150C>T p.I50= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs201247112, COSV65486178; called by muse, mutect2, varscan2
- HRNR | c.2988C>T p.H996= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as rs150171173; called by muse, mutect2, varscan2
- INTS1 | c.1932C>G p.S644= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as rs778502259; called by muse, mutect2
- KPTN | c.300G>A p.T100= | Silent (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- LHCGR | c.933G>C p.V311= | Silent (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2, varscan2
- LRRC37A2 | c.3621G>A p.G1207= | Silent (SNP) | VAF 41/181 reads (23%) | catalogued as rs1445034557; called by muse, mutect2, varscan2
- MAP3K3 | c.390C>A p.S130= | Silent (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- METTL17 | c.705A>T p.S235= | Silent (SNP) | VAF 33/53 reads (62%) | called by muse, mutect2, varscan2
- NPHS1 | c.2644C>T p.L882= | Silent (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- OR11L1 | c.546G>T p.P182= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV63314143; called by muse, varscan2
- PCDHB2 | c.1707C>T p.N569= | Silent (SNP) | VAF 62/222 reads (28%) | catalogued as rs200168689, COSV50565563; called by muse, varscan2
- PLCE1 | c.2073G>A p.V691= | Silent (SNP) | VAF 29/70 reads (41%) | called by muse, mutect2, varscan2
- PLEKHG5 | c.936C>A p.G312= (on ENST00000400915 / NM_001042663.3; = p.G275= on NM_020631.6) | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- PPP6R2 | c.909C>T p.S303= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs547118539, COSV99324590; called by muse, mutect2, varscan2
- PSME3IP1 | c.438G>A p.K146= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as rs771274396; called by muse, mutect2, varscan2
- RNF121 | c.168C>T p.L56= | Silent (SNP) | VAF 13/145 reads (9%) | catalogued as rs763254619; called by muse, mutect2
- SHANK2 | c.2205G>A p.P735= | Silent (SNP) | VAF 24/394 reads (6%) | catalogued as rs367733874; called by muse, mutect2
- TNFSF11 | c.99G>A p.P33= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs1333372975, COSV53478808; called by muse, mutect2, varscan2
- TSACC | c.156G>T p.L52= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as rs1323269460, COSV100966237; called by muse, mutect2
- AL353804.7 | chrX:73848680 G>A | 5'Flank (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- BIRC8 | n.1314G>A | RNA (SNP) | VAF 15/63 reads (24%) | catalogued as COSV70346412; called by muse, mutect2, varscan2
- CPLANE1 | c.*4336C>T | 3'UTR (SNP) | VAF 24/40 reads (60%) | catalogued as COSV99951882; called by muse, mutect2, varscan2
- EPCAM | c.555+690C>T | Intron (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
